Somatic mutation profile of tumor specimen C3L-08144-01 (aliquot CPT0511020005) from CPTAC case C3L-08144, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 72.0 years (26,311 days).
Specimen C3L-08144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43348d20-31b2-46f0-bb2f-14210e5771bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08144-31 (Blood Derived Normal), aliquot CPT0511010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76c8a864-ca69-44c3-9a86-ccc255116750

The open-access MAF lists 373 somatic variants for this specimen: 285 protein-altering or splice-affecting, 84 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 84, Frame Shift Del 5, Nonsense Mutation 4, Splice Region 2, Intron 2, Splice Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>C p.K1003T (on ENST00000280758 / NM_001018072.2; = p.K540T on NM_001017523.2) | Missense Mutation (SNP) | VAF 92/400 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2, varscan2
- ABCA13 | c.13918T>G p.F4640V | Missense Mutation (SNP) | VAF 189/562 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV68945836; called by muse, mutect2, varscan2
- ACTRT3 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 51/1180 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as rs369953876; called by muse, mutect2
- ADAMTS19 | c.1794G>A p.W598* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV50807781; called by muse, varscan2
- ADAMTSL1 | c.1511A>C p.K504T | Missense Mutation (SNP) | VAF 74/390 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV52815086; called by muse, mutect2, varscan2
- AFG1L | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 74/500 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.078); catalogued as rs756443552, COSV64555663; called by muse, mutect2, varscan2
- ARPP21 | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 94/466 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs1196024489; called by muse, mutect2, varscan2
- ATAD2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54881389, COSV54888536; called by muse, varscan2
- AUTS2 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV61390323; called by muse, mutect2, varscan2
- BRCA1 | c.4743A>T p.E1581D | Missense Mutation (SNP) | VAF 311/983 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as CM065003; called by muse, mutect2, varscan2
- BRINP2 | c.298T>G p.L100V | Missense Mutation (SNP) | VAF 147/879 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV64176143, COSV64180931; called by muse, mutect2, varscan2
- C1QTNF12 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 52/1084 reads (5%) | catalogued as COSV100382539; called by muse, mutect2
- CACNB2 | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 122/1250 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as rs1564288218; called by muse, mutect2
- CELA2B | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 173/1314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756679268; called by muse, mutect2, varscan2
- CHGB | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 61/731 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs778818539; called by muse, mutect2
- CHST9 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1291133808, COSV52432602, COSV52444029; called by muse, mutect2, varscan2
- CLDN17 | c.194A>T p.K65M | Missense Mutation (SNP) | VAF 34/843 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54524453; called by muse, mutect2
- COL4A1 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 176/585 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs150866172; called by muse, mutect2, varscan2
- COL6A6 | c.4279A>G p.R1427G | Missense Mutation (SNP) | VAF 22/556 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355219095; called by muse, mutect2
- CRISPLD1 | c.563A>C p.N188T | Missense Mutation (SNP) | VAF 75/509 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100082419; called by muse, mutect2, varscan2
- CSMD1 | c.1299A>C p.E433D (on ENST00000520002; = p.E432D on NM_033225.6) | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.926); catalogued as COSV68169908; called by muse, mutect2, varscan2
- CTNNBL1 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 104/538 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs779458238; called by muse, mutect2, varscan2
- CYFIP2 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV59036688, COSV59038387; called by muse, mutect2
- DCAF12L2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 163/519 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs781622794, COSV100758816, COSV63583978; called by muse, mutect2, varscan2
- DCDC1 | c.2708T>G p.L903R (on ENST00000597505 / NM_001367979.1; = p.L10R on NM_020869.3) | Missense Mutation (SNP) | VAF 81/435 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100338031; called by muse, mutect2, varscan2
- DDX51 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 227/829 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1230879922; called by muse, mutect2, varscan2
- DENND2A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 211/951 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs766779073, COSV52050018; called by muse, mutect2, varscan2
- DNAI2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 208/1240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs767042349, COSV56763820; called by muse, mutect2, varscan2
- EBF2 | c.1468T>G p.L490V | Missense Mutation (SNP) | VAF 37/699 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1156879434, COSV68778596, COSV68780628; called by muse, mutect2
- EIF4E3 | c.373G>T p.V125L (on ENST00000425534 / NM_001134651.2; = p.V19L on NM_173359.5) | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.36); catalogued as COSV55204495; called by muse, mutect2
- EPHA3 | c.1876G>T p.V626F | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60733466; called by muse, mutect2, varscan2
- EPHA3 | c.1925T>G p.L642R | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60700624; called by muse, mutect2, varscan2
- ERAP1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201066303; called by muse, mutect2, varscan2
- FAM110B | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 157/789 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403944505, COSV64067599; called by muse, mutect2, varscan2
- FAM189A1 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 46/832 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1260132789, COSV54264650; called by muse, mutect2
- FBN2 | c.1765G>A p.G589S | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057523294, COSV52543298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIGN | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 77/715 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV60766138; called by muse, mutect2, varscan2
- FOXP2 | c.1664A>C p.N555T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63485795; called by muse, mutect2, varscan2
- FREM2 | c.4333A>G p.S1445G | Missense Mutation (SNP) | VAF 76/838 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV54826736; called by muse, mutect2
- GDAP1L1 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 239/941 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61157642; called by muse, mutect2, varscan2
- GLRA1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 61/429 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs766445967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR158 | c.3472A>C p.S1158R | Missense Mutation (SNP) | VAF 102/850 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as COSV66269337; called by muse, mutect2, varscan2
- GPR26 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 244/946 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.149); catalogued as rs1278697193, COSV99501141; called by muse, mutect2, varscan2
- GPR78 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 174/888 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.28); catalogued as rs527979936, COSV66762514, COSV66762677; called by muse, mutect2
- GRIN2A | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs763500409, COSV58053815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM6 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 50/1134 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as rs150850494; called by muse, mutect2
- GRM7 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 106/629 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs753302178, COSV100737974; called by muse, mutect2, varscan2
- GRM8 | c.2453T>C p.L818P | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58829629, COSV58836480; called by muse, mutect2, varscan2
- HMCN1 | c.2720T>G p.L907R | Missense Mutation (SNP) | VAF 99/632 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV54891771; called by muse, mutect2, varscan2
- HOXB1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 428/1348 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1422685937, COSV53316490; called by muse, mutect2, varscan2
- HTR5A | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 115/1034 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55280167; called by muse, mutect2, varscan2
- IRX1 | c.1304C>A p.T435K | Missense Mutation (SNP) | VAF 92/1502 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1197001451; called by muse, mutect2
- ITGA8 | c.681A>C p.Q227H | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV65224788; called by muse, mutect2, varscan2
- ITPR1 | c.4166A>G p.K1389R (on ENST00000354582; = p.K1374R on NM_002222.7) | Missense Mutation (SNP) | VAF 192/666 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs913863975; called by muse, mutect2, varscan2
- KCNB2 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 127/766 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV73051790; called by muse, mutect2, varscan2
- KCNQ3 | c.1912T>G p.F638V | Missense Mutation (SNP) | VAF 85/638 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1174104987; called by muse, mutect2, varscan2
- KCNS3 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 44/722 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760585114, COSV100411609; called by muse, mutect2
- KIR2DL3 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 108/678 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1355373989; called by muse, mutect2, varscan2
- KNL1 | c.520G>A p.E174K (on ENST00000346991 / NM_170589.5; = p.E148K on NM_144508.5) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1043256244, COSV100706077; called by muse, mutect2, varscan2
- KRT9 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 71/614 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs140000246; called by muse, mutect2, varscan2
- LAMA1 | c.8810T>C p.V2937A | Missense Mutation (SNP) | VAF 102/736 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV67532310; called by muse, mutect2, varscan2
- LAMA1 | c.8329T>G p.F2777V | Missense Mutation (SNP) | VAF 28/1015 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV67532119; called by muse, mutect2
- LCE2B | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 163/1316 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs145964810, COSV64227905; called by muse, mutect2, varscan2
- LGALS14 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 52/758 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1347974912, COSV62372311; called by muse, mutect2
- LRIG2 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV63161467; called by muse, mutect2, varscan2
- LRP2 | c.9848A>G p.K3283R | Missense Mutation (SNP) | VAF 73/494 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1165575525; called by muse, mutect2, varscan2
- LRRC30 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 125/799 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV67302280; called by muse, mutect2, varscan2
- MAGEC3 | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 175/435 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71610184; called by muse, mutect2, varscan2
- MGAT1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 263/902 reads (29%) | PolyPhen probably damaging (0.956); catalogued as rs1475126056, COSV57135422; called by muse, mutect2, varscan2
- MUC15 | c.989T>G p.L330R | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV99846186, COSV99846319; called by muse, mutect2
- MUC16 | c.26587A>C p.T8863P | Missense Mutation (SNP) | VAF 135/499 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs1568793768, COSV67461464; called by muse, mutect2, varscan2
- MX1 | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 180/756 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV104385429; called by muse, mutect2, varscan2
- NBPF9 | c.1851C>T p.P617= | Splice Region (SNP) | VAF 22/689 reads (3%) | catalogued as COSV56011588; called by muse, mutect2
- NLRP12 | c.2231T>C p.L744P | Missense Mutation (SNP) | VAF 84/686 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1255196444; called by muse, mutect2, varscan2
- OR2A4 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs371297064, COSV59576301; called by muse, mutect2, varscan2
- OR2L8 | c.61A>G p.R21G | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100594029, COSV100594290; called by muse, mutect2, varscan2
- OR2L8 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 52/750 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs565612069, COSV100594400, COSV61727112; called by muse, mutect2
- OR2M7 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 80/691 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58738919; called by muse, mutect2, varscan2
- OR5F1 | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV53546632, COSV53546830; called by muse, mutect2
- PCDHA7 | c.1782del p.R595Vfs*43 | Frame Shift Del (DEL) | VAF 169/721 reads (23%) | catalogued as COSV65345562; called by mutect2, pindel, varscan2
- PEG3 | c.2282A>C p.K761T | Missense Mutation (SNP) | VAF 34/600 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55627288, COSV99688396; called by muse, mutect2
- PLD5 | c.1357A>C p.N453H (on ENST00000442594; = p.N391H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100140555, COSV59160447; called by muse, mutect2
- PLIN1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 186/1052 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1280527702, COSV55582882, COSV55583667; called by muse, mutect2, varscan2
- PRDM6 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.791); catalogued as rs1023772422; called by muse, mutect2, varscan2
- PRPF39 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs769016580; called by muse, varscan2
- RASGRF1 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 99/738 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1234815073, COSV69181774; called by muse, varscan2
- RBM19 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 122/472 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as rs1414361544, COSV99926786; called by muse, mutect2, varscan2
- RGS6 | c.802T>G p.L268V | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV59601697; called by muse, mutect2, varscan2
- RIMS1 | c.3358T>G p.L1120V | Missense Mutation (SNP) | VAF 21/451 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.977); catalogued as rs1237700419, COSV99324762; called by muse, mutect2
- RPL10L | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 102/671 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53559335, COSV53559592; called by muse, mutect2, varscan2
- RTL3 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 140/526 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.667); catalogued as COSV100330043; called by muse, mutect2, varscan2
- SCG2 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as rs1462019509, COSV59539101; called by muse, mutect2
- SFMBT2 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62816358; called by muse, mutect2
- SLC15A1 | c.1212del p.N404Kfs*4 | Frame Shift Del (DEL) | VAF 33/174 reads (19%) | catalogued as COSV64733111; called by mutect2, pindel, varscan2
- SNED1 | c.2038T>G p.F680V | Missense Mutation (SNP) | VAF 54/1161 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60020403; called by muse, mutect2
- STARD9 | c.5728T>C p.F1910L | Missense Mutation (SNP) | VAF 31/547 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1433655879; called by muse, mutect2
- TAF4B | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.522); catalogued as COSV52302152; called by muse, mutect2, varscan2
- TFAP2B | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 122/1366 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV53828563; called by muse, mutect2
- TIE1 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 259/916 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs767953419; called by muse, mutect2, varscan2
- TK2 | c.200G>A p.R67H (on ENST00000299697; = p.R123H on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/669 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs766332476, COSV55283812; called by muse, mutect2, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 234/486 reads (48%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- TRBV23-1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772015492; called by muse, mutect2, varscan2
- TRPC4 | c.2350G>A p.E784K (on ENST00000379705 / NM_016179.4; = p.E789K on NM_003306.3) | Missense Mutation (SNP) | VAF 80/780 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs756533828, COSV58997184; called by muse, mutect2
- TTN | c.49399A>C p.S16467R (on ENST00000591111; = p.S9043R on NM_003319.4) | Missense Mutation (SNP) | VAF 66/364 reads (18%) | PolyPhen benign (0.018); catalogued as rs1460827160, COSV60419356; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/306 reads (5%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2
- TTN | c.48189A>C p.K16063N (on ENST00000591111; = p.K8639N on NM_003319.4) | Missense Mutation (SNP) | VAF 33/742 reads (4%) | PolyPhen benign (0.075); catalogued as COSV60068944; called by muse, mutect2
- TYR | c.805T>C p.F269L | Missense Mutation (SNP) | VAF 65/522 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54470967, COSV99633214; called by muse, mutect2, varscan2
- VGF | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 149/799 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.746); catalogued as rs35400704, COSV50801779, COSV99972772, COSV99973099; called by muse, mutect2, varscan2
- XIRP2 | c.3083A>C p.K1028T (on ENST00000628543; = p.K1203T on NM_152381.6) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as rs996282343; called by muse, mutect2, varscan2
- XIRP2 | c.6804A>C p.K2268N (on ENST00000628543; = p.K2443N on NM_152381.6) | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV54704229; called by muse, mutect2
- YTHDC1 | c.2156G>A p.R719Q (on ENST00000344157 / NM_001031732.4; = p.R701Q on NM_133370.4) | Missense Mutation (SNP) | VAF 80/539 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.885); catalogued as rs368902802; called by muse, mutect2, varscan2
- ZBTB32 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 258/1694 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1463389461; called by muse, mutect2
- ZFHX2 | c.6434G>A p.R2145H | Missense Mutation (SNP) | VAF 38/1354 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.753); catalogued as rs867863287, COSV101352222, COSV70220267; called by muse, mutect2
- ZNF215 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 101/722 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99549148; called by muse, mutect2, varscan2
- ZNF329 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 120/788 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs539267795, COSV100798679; called by muse, varscan2
- ZNF502 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV56072660; called by muse, mutect2, varscan2
- ZNF534 | c.654A>C p.Q218H (on ENST00000332323 / NM_001143939.3; = p.Q205H on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV56517240, COSV99990144; called by muse, mutect2, varscan2
- ZNF703 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 94/1060 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs781488489; called by muse, mutect2
- ZNF790 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV63211927, COSV63212088; called by muse, mutect2, varscan2
- ABCA13 | c.2720T>C p.F907S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ABCA13 | c.14396T>C p.L4799P | Missense Mutation (SNP) | VAF 101/786 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ABCC9 | c.2806A>C p.T936P | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.487); called by muse, mutect2
- ABCG8 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 277/940 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACSM2B | c.1616A>C p.K539T | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADA2 | c.869A>G p.Y290C (on ENST00000262607; = p.Y49C on NM_177405.3) | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ADAMTS12 | c.3874A>C p.S1292R | Missense Mutation (SNP) | VAF 143/1806 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2
- ADARB2 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 183/1612 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADCY2 | c.1618T>G p.L540V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.022); called by muse, varscan2
- ADCY8 | c.2052A>C p.R684S | Missense Mutation (SNP) | VAF 60/1038 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.159); called by muse, mutect2
- ADGRB3 | c.1865T>A p.I622N | Missense Mutation (SNP) | VAF 75/692 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ANGPT1 | c.443T>G p.V148G | Missense Mutation (SNP) | VAF 77/484 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30A | c.509A>T p.K170M (on ENST00000611781; = p.K114M on NM_052997.2) | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANO5 | c.2645A>C p.N882T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ARHGEF12 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 136/677 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BHLHE22 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 214/952 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C10orf53 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 152/794 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, varscan2
- C10orf90 | c.901T>G p.L301V | Missense Mutation (SNP) | VAF 69/571 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- C8orf48 | c.266A>C p.N89T | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CBLN1 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 54/1127 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2
- CCDC105 | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.17234T>G p.L5745R | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.6); called by muse, mutect2
- CD1C | c.469A>C p.S157R | Missense Mutation (SNP) | VAF 163/1052 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CFHR4 | c.1422A>C p.K474N (on ENST00000367416 / NM_001201551.2; = p.K228N on NM_006684.5) | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CFTR | c.4069G>A p.A1357T | Missense Mutation (SNP) | VAF 38/822 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHODL | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 152/867 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLDN16 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 54/452 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CNGA1 | c.1476A>C p.Q492H | Missense Mutation (SNP) | VAF 150/512 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CNGA1 | c.684A>C p.E228D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN2 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 34/1320 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- COL10A1 | c.1930C>G p.L644V | Missense Mutation (SNP) | VAF 95/662 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL4A5 | c.4273G>T p.D1425Y | Missense Mutation (SNP) | VAF 133/436 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CRYZ | c.946A>C p.I316L | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD2 | c.1155A>C p.K385N | Missense Mutation (SNP) | VAF 133/646 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CTNND2 | c.2544A>T p.K848N | Missense Mutation (SNP) | VAF 134/1611 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2
- CYFIP2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DACH1 | c.797T>A p.L266H | Missense Mutation (SNP) | VAF 25/854 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCDC1 | c.1787del p.D596Afs*3 | Frame Shift Del (DEL) | VAF 57/235 reads (24%) | called by mutect2, pindel, varscan2
- DDX59 | c.998T>G p.L333R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- DHRS3 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 148/925 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.7927A>C p.T2643P | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH5 | c.5552T>G p.F1851C | Missense Mutation (SNP) | VAF 49/817 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2
- DNAJC13 | c.2875-1G>A p.X959_splice | Splice Site (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- DOCK2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- DPPA4 | c.805T>G p.F269V | Missense Mutation (SNP) | VAF 39/1529 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EDNRB | c.1500A>C p.E500D (on ENST00000377211 / NM_001201397.1; = p.E410D on NM_000115.5) | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF2S3B | c.810A>C p.E270D | Missense Mutation (SNP) | VAF 46/596 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.899); called by muse, mutect2
- EIF4G3 | c.2585T>G p.L862R | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- ELMO1 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- EML5 | c.5222T>C p.V1741A (on ENST00000380664; = p.V1749A on NM_183387.3) | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYS | c.4366A>C p.S1456R | Missense Mutation (SNP) | VAF 33/719 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- EYS | c.2185A>G p.R729G | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FAM131C | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 214/1302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM168B | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 124/793 reads (16%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- FASTKD1 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FAT3 | c.3006A>T p.K1002N | Missense Mutation (SNP) | VAF 97/778 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- FBN1 | c.4903A>C p.T1635P | Missense Mutation (SNP) | VAF 39/610 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- FHL5 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 86/598 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- FLG | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 56/1610 reads (3%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); called by muse, mutect2
- FMN2 | c.1850A>T p.Q617L | Missense Mutation (SNP) | VAF 83/709 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- FRMD6 | c.1728A>C p.E576D (on ENST00000344768 / NM_001267046.2; = p.E568D on NM_152330.4) | Missense Mutation (SNP) | VAF 50/1030 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- FSHR | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- GABRE | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); called by muse, mutect2
- GOLGA6L2 | c.1174A>G p.M392V | Missense Mutation (SNP) | VAF 58/1120 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- GPR174 | c.880T>A p.F294I | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.550A>C p.S184R | Missense Mutation (SNP) | VAF 102/512 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCN1 | c.272A>T p.Y91F | Missense Mutation (SNP) | VAF 146/1055 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.119); called by muse, varscan2
- IFI16 | c.716T>G p.F239C | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- IGSF1 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 156/635 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITIH2 | c.1898A>G p.E633G | Missense Mutation (SNP) | VAF 126/1229 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNE2 | c.301T>G p.L101V | Missense Mutation (SNP) | VAF 165/775 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH1 | c.700T>G p.L234V | Missense Mutation (SNP) | VAF 112/837 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KLK11 | c.388T>G p.F130V (on ENST00000594768 / NM_144947.3; = p.F98V on NM_006853.3) | Missense Mutation (SNP) | VAF 177/1432 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KLK3 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 102/1060 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2
- KMT2B | c.2876A>G p.K959R | Missense Mutation (SNP) | VAF 236/1540 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- L3MBTL4 | c.1784T>C p.L595P | Missense Mutation (SNP) | VAF 24/850 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LCOR | c.3043T>G p.L1015V | Missense Mutation (SNP) | VAF 180/679 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LDB2 | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 23/710 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP2 | c.3928T>C p.F1310L | Missense Mutation (SNP) | VAF 226/985 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MACF1 | c.1451T>C p.I484T | Missense Mutation (SNP) | VAF 104/1132 reads (9%) | called by muse, mutect2
- MAGEL2 | c.2475T>A p.F825L | Missense Mutation (SNP) | VAF 25/940 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2
- MAP7D3 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 270/777 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MAPT | c.763_767del p.G255Pfs*5 (on ENST00000262410 / NM_001377265.1; = p.G180Pfs*5 on NM_016835.4) | Frame Shift Del (DEL) | VAF 644/2403 reads (27%) | called by mutect2, pindel, varscan2
- MCF2 | c.1140A>C p.E380D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL24 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- MEX3C | c.1751C>T p.T584I | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2
- MICAL3 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 137/551 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT6 | c.2350C>T p.Q784* | Nonsense Mutation (SNP) | VAF 223/1110 reads (20%) | called by muse, mutect2, varscan2
- MMS19 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 27/614 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.013); called by muse, mutect2
- MUC2 | c.4159A>C p.N1387H | Missense Mutation (SNP) | VAF 101/677 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MYH9 | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 170/578 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, varscan2
- MYT1L | c.2245A>T p.S749C | Missense Mutation (SNP) | VAF 32/892 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2
- MYT1L | c.1546A>C p.T516P | Missense Mutation (SNP) | VAF 36/678 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAV3 | c.2174T>G p.V725G | Missense Mutation (SNP) | VAF 19/514 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NELL1 | c.2113A>C p.S705R | Missense Mutation (SNP) | VAF 115/581 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NLRP12 | c.2230C>T p.L744F | Missense Mutation (SNP) | VAF 86/692 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NRG1 | c.188A>C p.E63A (on ENST00000523534; = p.E210A on NM_013962.2) | Missense Mutation (SNP) | VAF 62/761 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- NVL | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 118/664 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR13C3 | c.328T>G p.S110A | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2
- OR2AG1 | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 38/443 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- OR4A15 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR4K14 | c.33A>C p.E11D | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- OR52A5 | c.845T>A p.L282H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR5L2 | c.893A>C p.N298T | Missense Mutation (SNP) | VAF 49/516 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR5M8 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 30/735 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- OR7E24 | c.274A>C p.T92P | Missense Mutation (SNP) | VAF 133/474 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- OR8D4 | c.924A>T p.K308N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR8K5 | c.643T>G p.L215V | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAPOLB | c.1689G>A p.M563I | Missense Mutation (SNP) | VAF 94/794 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPSS1 | c.1517A>T p.H506L | Missense Mutation (SNP) | VAF 39/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCNT | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 86/632 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PDE7B | c.1052T>G p.L351R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PHACTR3 | c.506A>T p.K169M | Missense Mutation (SNP) | VAF 183/1309 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PRAMEF11 | c.392A>G p.K131R | Missense Mutation (SNP) | VAF 181/977 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PRAMEF20 | c.1289T>G p.F430C | Missense Mutation (SNP) | VAF 44/1230 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- PRELP | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 156/1032 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRC2B | c.6038C>T p.S2013F | Missense Mutation (SNP) | VAF 219/862 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PRRC2C | c.2966C>T p.S989F (on ENST00000367742; = p.S987F on NM_015172.4) | Missense Mutation (SNP) | VAF 147/344 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PSMD13 | c.389T>G p.V130G | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRZ1 | c.4024A>C p.S1342R | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBP5 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 131/516 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- RIMBP2 | c.306A>G p.K102= | Splice Region (SNP) | VAF 114/589 reads (19%) | called by muse, mutect2, varscan2
- RTL3 | c.84A>C p.E28D | Missense Mutation (SNP) | VAF 119/486 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RYR2 | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 80/507 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- RYR3 | c.1183T>G p.L395V | Missense Mutation (SNP) | VAF 115/593 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SCN9A | c.2204A>G p.K735R (on ENST00000303354; = p.K724R on NM_002977.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA6D | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 84/461 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SEMA6D | c.2939A>C p.N980T (on ENST00000316364 / NM_153618.2; = p.N918T on NM_020858.2) | Missense Mutation (SNP) | VAF 108/509 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SETDB1 | c.2006A>G p.K669R | Missense Mutation (SNP) | VAF 46/824 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2
- SETDB2 | c.225A>C p.E75D | Missense Mutation (SNP) | VAF 141/671 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFRP4 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 102/566 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SH3GL3 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIK3 | c.1343C>T p.P448L (on ENST00000445177 / NM_001366686.2; = p.P454L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/842 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2
- SLC10A7 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC35F1 | c.1016A>C p.Y339S | Missense Mutation (SNP) | VAF 94/451 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLITRK3 | c.1928A>G p.E643G | Missense Mutation (SNP) | VAF 48/1418 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- SOX30 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 167/544 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A3 | c.2212T>G p.L738V | Missense Mutation (SNP) | VAF 135/784 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SPATA31A3 | c.1929G>A p.W643* | Nonsense Mutation (SNP) | VAF 62/1123 reads (6%) | called by muse, mutect2
- SSTR2 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 201/1263 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SYT3 | c.628A>G p.S210G | Missense Mutation (SNP) | VAF 120/1273 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.045); called by muse, mutect2
- TAF1L | c.1625A>C p.N542T | Missense Mutation (SNP) | VAF 169/589 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TECPR2 | c.2558A>G p.Q853R | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TENM1 | c.2676A>C p.Q892H | Missense Mutation (SNP) | VAF 20/411 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2
- TEX13C | c.2141A>C p.K714T | Missense Mutation (SNP) | VAF 52/958 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); called by muse, mutect2
- TLR4 | c.1299T>G p.N433K (on ENST00000355622 / NM_138554.5; = p.N393K on NM_003266.4) | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TNRC6C | c.2203A>C p.S735R | Missense Mutation (SNP) | VAF 155/809 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TOPAZ1 | c.2561T>G p.L854R | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TPTE | c.1578T>G p.I526M (on ENST00000618007 / NM_199261.4; = p.I508M on NM_199259.4) | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2
- TRHR | c.149T>A p.V50D | Missense Mutation (SNP) | VAF 129/710 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM49C | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TRIM64B | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 110/1474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSPOAP1 | c.4241A>C p.K1414T | Missense Mutation (SNP) | VAF 322/1178 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TTC21A | c.1636T>G p.L546V | Missense Mutation (SNP) | VAF 145/647 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TTN | c.66941A>T p.K22314I (on ENST00000591111; = p.K14890I on NM_003319.4) | Missense Mutation (SNP) | VAF 29/508 reads (6%) | PolyPhen possibly damaging (0.878); called by muse, mutect2
- TTN | c.62610A>T p.K20870N (on ENST00000591111; = p.K13446N on NM_003319.4) | Missense Mutation (SNP) | VAF 56/303 reads (18%) | PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TTN | c.13908A>C p.K4636N (on ENST00000591111; = p.K3709N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/522 reads (4%) | PolyPhen probably damaging (0.943); called by muse, mutect2
- UNC13C | c.6413A>C p.K2138T | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC5C | c.154A>C p.T52P | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- VCAN | c.2015T>G p.I672S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- VCAN | c.2120T>C p.I707T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- VCAN | c.2308T>C p.F770L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF215 | c.1174T>A p.S392T | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF329 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 99/868 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- ZNF717 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZNF837 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 190/1688 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ABCA13 | c.10038T>G p.T3346= | Silent (SNP) | VAF 28/536 reads (5%) | catalogued as COSV101446738, COSV101446901; called by muse, mutect2
- ABCA13 | c.15166T>C p.L5056= | Silent (SNP) | VAF 41/252 reads (16%) | called by muse, mutect2, varscan2
- ADGRG4 | c.3513T>G p.T1171= | Silent (SNP) | VAF 174/487 reads (36%) | called by muse, mutect2, varscan2
- B3GALNT2 | c.384G>A p.A128= | Silent (SNP) | VAF 296/732 reads (40%) | catalogued as rs1049290415, COSV100010008; called by muse, mutect2, varscan2
- B3GAT3 | c.834C>T p.G278= | Silent (SNP) | VAF 173/1178 reads (15%) | catalogued as COSV53882512, COSV53884537; called by mutect2, varscan2
- BTN2A1 | c.183C>T p.D61= | Silent (SNP) | VAF 203/1089 reads (19%) | catalogued as rs759949879; called by muse, mutect2, varscan2
- C1QTNF4 | c.384C>T p.Y128= | Silent (SNP) | VAF 54/1571 reads (3%) | catalogued as rs1266773010; called by muse, mutect2
- CAVIN2 | c.891C>T p.F297= | Silent (SNP) | VAF 144/546 reads (26%) | catalogued as COSV100414201; called by muse, mutect2, varscan2
- CCDC178 | c.1068A>C p.S356= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- CEACAM16 | c.1134C>G p.G378= | Silent (SNP) | VAF 46/1876 reads (2%) | called by muse, mutect2
- CENPU | c.9G>A p.P3= | Silent (SNP) | VAF 69/1150 reads (6%) | catalogued as rs1307045026; called by muse, mutect2
- CFAP54 | c.8739T>G p.S2913= | Silent (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2, varscan2
- CHAT | c.879G>A p.Q293= | Silent (SNP) | VAF 144/934 reads (15%) | called by muse, mutect2, varscan2
- CUBN | c.4959G>A p.A1653= | Silent (SNP) | VAF 51/480 reads (11%) | catalogued as rs577984421, COSV100913637, COSV64716458; called by muse, mutect2, varscan2
- DKK1 | c.720A>G p.G240= | Silent (SNP) | VAF 67/378 reads (18%) | called by muse, mutect2, varscan2
- DLL1 | c.177C>T p.F59= | Silent (SNP) | VAF 72/1690 reads (4%) | catalogued as rs913116172; ClinVar: likely benign; called by muse, mutect2
- DMXL1 | c.1599T>G p.A533= | Silent (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- DSCAML1 | c.3034T>C p.L1012= (on ENST00000321322; = p.L952= on NM_020693.4) | Silent (SNP) | VAF 210/947 reads (22%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.3352T>C p.L1118= | Silent (SNP) | VAF 58/328 reads (18%) | called by muse, mutect2, varscan2
- EIF2S2 | c.54G>A p.K18= | Silent (SNP) | VAF 59/235 reads (25%) | called by muse, mutect2, varscan2
- ENOX1 | c.762C>T p.S254= | Silent (SNP) | VAF 167/1343 reads (12%) | called by muse, mutect2, varscan2
- EPS8L1 | c.642G>A p.A214= (on ENST00000201647 / NM_133180.3; = p.A87= on NM_017729.3) | Silent (SNP) | VAF 200/2684 reads (7%) | catalogued as rs1568785008, COSV99136798; called by muse, mutect2
- EYS | c.951T>G p.T317= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs993944802, COSV61001622; called by muse, mutect2, varscan2
- FAM124B | c.936T>G p.T312= | Silent (SNP) | VAF 118/872 reads (14%) | catalogued as rs1468558656; called by muse, mutect2, varscan2
- FMN2 | c.1482C>T p.P494= | Silent (SNP) | VAF 295/1932 reads (15%) | called by muse, mutect2, varscan2
- FOXK1 | c.408G>A p.L136= | Silent (SNP) | VAF 45/1391 reads (3%) | called by muse, mutect2
- GALT | c.1110G>A p.Q370= | Silent (SNP) | VAF 141/468 reads (30%) | called by muse, mutect2, varscan2
- GPR139 | c.897G>A p.T299= | Silent (SNP) | VAF 191/688 reads (28%) | catalogued as rs758294318, COSV100429827, COSV58503668; called by muse, mutect2, varscan2
- GPRIN1 | c.1884G>A p.G628= | Silent (SNP) | VAF 37/874 reads (4%) | catalogued as rs1480525870; called by muse, mutect2
- IGSF10 | c.1923T>G p.G641= | Silent (SNP) | VAF 162/726 reads (22%) | catalogued as rs780467516; called by muse, mutect2, varscan2
- IPP | c.561G>A p.L187= | Silent (SNP) | VAF 60/511 reads (12%) | called by muse, mutect2, varscan2
- IRX4 | c.1236G>A p.T412= | Silent (SNP) | VAF 242/3004 reads (8%) | called by muse, mutect2
- KCNH8 | c.2764T>C p.L922= | Silent (SNP) | VAF 39/806 reads (5%) | called by muse, mutect2
- KRTAP15-1 | c.198T>G p.T66= | Silent (SNP) | VAF 26/776 reads (3%) | catalogued as COSV61878158; called by muse, mutect2
- LMX1A | c.531A>G p.S177= | Silent (SNP) | VAF 49/1178 reads (4%) | called by muse, mutect2
- LRRC9 | c.2625A>G p.L875= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- MAP2 | c.618T>G p.T206= | Silent (SNP) | VAF 19/628 reads (3%) | catalogued as COSV52285788; called by muse, mutect2
- MAP2 | c.3972T>A p.S1324= | Silent (SNP) | VAF 94/526 reads (18%) | called by muse, mutect2, varscan2
- MAP2 | c.4830T>G p.S1610= | Silent (SNP) | VAF 125/773 reads (16%) | catalogued as COSV52284688, COSV52309260, COSV99561686; called by muse, mutect2, varscan2
- MGAT4B | c.1404G>A p.V468= | Silent (SNP) | VAF 115/601 reads (19%) | called by muse, mutect2, varscan2
- MOCS1 | c.1428G>A p.Q476= | Silent (SNP) | VAF 111/824 reads (13%) | called by muse, mutect2, varscan2
- NDST3 | c.147A>G p.E49= | Silent (SNP) | VAF 27/432 reads (6%) | called by muse, mutect2
- NDST4 | c.2415T>G p.G805= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs772708828; called by muse, mutect2, varscan2
- NPAS1 | c.1404C>T p.G468= | Silent (SNP) | VAF 183/1940 reads (9%) | called by muse, mutect2
- NPY5R | c.1062T>G p.R354= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- OR12D3 | c.885A>G p.E295= | Silent (SNP) | VAF 111/935 reads (12%) | called by muse, mutect2
- OR4C15 | c.346T>C p.L116= (on ENST00000314644; = p.L62= on NM_001001920.2) | Silent (SNP) | VAF 24/778 reads (3%) | catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2
- OR4N2 | c.310T>C p.L104= | Silent (SNP) | VAF 230/2439 reads (9%) | catalogued as rs748506496; called by muse, mutect2
- OR52A1 | c.213A>G p.T71= | Silent (SNP) | VAF 81/559 reads (14%) | called by muse, mutect2, varscan2
- OR52E5 | c.499A>C p.R167= | Silent (SNP) | VAF 21/753 reads (3%) | called by muse, mutect2
- PDZD8 | c.393G>T p.L131= | Silent (SNP) | VAF 278/939 reads (30%) | called by muse, mutect2, varscan2
- PEX14 | c.429G>A p.K143= | Silent (SNP) | VAF 168/1922 reads (9%) | called by muse, mutect2
- PLCB2 | c.2382G>A p.A794= | Silent (SNP) | VAF 327/690 reads (47%) | catalogued as rs779878465, COSV99541889; called by muse, mutect2, varscan2
- PPT1 | c.546C>T p.A182= (on ENST00000433473; = p.A183= on NM_000310.4) | Silent (SNP) | VAF 104/691 reads (15%) | catalogued as rs1408279040, COSV65654876, COSV65655256; called by muse, mutect2, varscan2
- PRAMEF15 | c.69A>G p.Q23= | Silent (SNP) | VAF 260/1623 reads (16%) | called by muse, mutect2, varscan2
- PRKCA | c.1842C>T p.F614= | Silent (SNP) | VAF 65/458 reads (14%) | catalogued as COSV101151236; called by muse, mutect2, varscan2
- PTCH2 | c.864C>T p.H288= | Silent (SNP) | VAF 52/1329 reads (4%) | called by muse, mutect2
- PTCHD3 | c.462C>T p.T154= | Silent (SNP) | VAF 154/1596 reads (10%) | catalogued as rs763146945, COSV71257196; called by muse, mutect2
- RAB3GAP2 | c.2512C>T p.L838= | Silent (SNP) | VAF 104/1032 reads (10%) | called by muse, mutect2, varscan2
- RANBP3 | c.990A>G p.R330= (on ENST00000340578 / NM_007322.3; = p.R325= on NM_003624.3) | Silent (SNP) | VAF 135/497 reads (27%) | called by muse, mutect2, varscan2
- REG1A | c.279T>C p.T93= | Silent (SNP) | VAF 90/562 reads (16%) | catalogued as rs778639370; called by muse, mutect2, varscan2
- RIMS2 | c.4107A>G p.T1369= (on ENST00000666250 / NM_001348490.2; = p.T940= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 22/820 reads (3%) | catalogued as COSV51701663; called by muse, mutect2
- RORC | c.1263A>G p.T421= | Silent (SNP) | VAF 104/675 reads (15%) | called by muse, mutect2, varscan2
- SACS | c.7617T>C p.Y2539= | Silent (SNP) | VAF 71/412 reads (17%) | called by muse, mutect2, varscan2
- SACS | c.6819A>C p.S2273= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV66539247; called by muse, mutect2, varscan2
- SERPINE2 | c.153C>T p.I51= | Silent (SNP) | VAF 207/891 reads (23%) | catalogued as rs3795875, COSV51456866; called by muse, mutect2, varscan2
- SEZ6 | c.963A>G p.Q321= | Silent (SNP) | VAF 392/1938 reads (20%) | called by muse, mutect2, varscan2
- SLC22A6 | c.768G>A p.A256= | Silent (SNP) | VAF 313/966 reads (32%) | catalogued as rs537819964, COSV64560033; called by muse, mutect2, varscan2
- SLC6A20 | c.831C>T p.I277= | Silent (SNP) | VAF 51/836 reads (6%) | catalogued as COSV62071392; called by muse, mutect2
- SYNE1 | c.21804A>C p.A7268= (on ENST00000367255 / NM_182961.4; = p.A7197= on NM_033071.3) | Silent (SNP) | VAF 44/731 reads (6%) | called by muse, mutect2
- TCEAL6 | c.334A>C p.R112= | Silent (SNP) | VAF 223/1073 reads (21%) | called by muse, mutect2, varscan2
- TCEAL7 | c.72G>A p.P24= | Silent (SNP) | VAF 155/420 reads (37%) | catalogued as COSV100197123; called by muse, mutect2, varscan2
- TIMD4 | c.720T>G p.V240= | Silent (SNP) | VAF 52/206 reads (25%) | called by muse, varscan2
- TMPRSS6 | c.2268G>A p.P756= | Silent (SNP) | VAF 147/632 reads (23%) | catalogued as rs773403505; called by muse, mutect2, varscan2
- TRAV20 | c.156A>G p.R52= | Silent (SNP) | VAF 73/749 reads (10%) | called by muse, mutect2, varscan2
- TRHR | c.781A>C p.R261= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, varscan2
- TTN | c.85467A>G p.E28489= (on ENST00000591111; = p.E21065= on NM_003319.4) | Silent (SNP) | VAF 83/502 reads (17%) | called by muse, mutect2, varscan2
- UNC45B | c.2103C>T p.I701= | Silent (SNP) | VAF 134/694 reads (19%) | catalogued as COSV99268253; called by muse, mutect2, varscan2
- VCAN | c.1236T>G p.P412= | Silent (SNP) | VAF 172/557 reads (31%) | called by muse, mutect2, varscan2
- VCAN | c.1881T>A p.T627= | Silent (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- XIRP2 | c.849C>T p.D283= (on ENST00000628543; = p.D458= on NM_152381.6) | Silent (SNP) | VAF 98/493 reads (20%) | catalogued as rs1016587142; called by muse, mutect2, varscan2
- XPNPEP3 | c.478C>A p.R160= | Silent (SNP) | VAF 128/636 reads (20%) | called by muse, mutect2, varscan2
- ZNF213 | c.456G>A p.T152= | Silent (SNP) | VAF 222/852 reads (26%) | catalogued as rs138124749; called by muse, varscan2
- ZNF331 | c.810T>G p.P270= | Silent (SNP) | VAF 154/881 reads (17%) | catalogued as COSV53479795; called by muse, mutect2, varscan2
- AC010343.3 | n.270-26028A>T | Intron (SNP) | VAF 140/1824 reads (8%) | called by muse, mutect2
- DPP6 | c.244-140691C>T | Intron (SNP) | VAF 133/682 reads (20%) | catalogued as rs776572881, COSV59597378; called by muse, varscan2
- RBP1 | chr3:139539686 C>T | 5'Flank (SNP) | VAF 179/1146 reads (16%) | called by muse, mutect2, varscan2
- ZFP14 | chr19:36331677 T>C | 3'Flank (SNP) | VAF 109/959 reads (11%) | called by muse, mutect2, varscan2
